CPTAC case 02OV008 — Ovary — Cystic, Mucinous and Serous Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/d7e3db60-1891-494b-81cb-5412cab99f5d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Serous adenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Prior malignancy: no.

Biospecimens (2 samples)
- Sample 5ffd8c6c-0807-4be5-b0d1-dc475f: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Sample fbb41c94-aabd-49cc-90b2-882c3e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
